Somatic mutation profile of tumor specimen TCGA-AG-4015-01A (aliquot TCGA-AG-4015-01A-01W-1073-09) from TCGA case TCGA-AG-4015, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 85.7 years (31,291 days).
Specimen TCGA-AG-4015-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dd6c9ff-b2f7-48f8-96e6-fb4a8756b0d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-4015-10A (Blood Derived Normal), aliquot TCGA-AG-4015-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbe7b0ef-afaa-433d-941e-bca0e19d9d37

The open-access MAF lists 100 somatic variants for this specimen: 76 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 22, Nonsense Mutation 5, In Frame Del 2, Frame Shift Del 2, Splice Site 1, Intron 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 52/73 reads (71%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ACKR2 | c.1084A>G p.M362V | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV56177009; called by muse, mutect2, varscan2
- ALDH1L1 | c.2608G>A p.A870T | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as rs200290145, COSV56411228; called by muse, mutect2, varscan2
- AMY2A | c.151G>T p.G51* | Nonsense Mutation (SNP) | VAF 41/122 reads (34%) | catalogued as rs761137032, COSV70214313, COSV70214392; called by muse, mutect2, varscan2
- ANKFN1 | c.555C>A p.N185K | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59441901; called by muse, mutect2, varscan2
- APC | c.4128T>A p.Y1376* | Nonsense Mutation (SNP) | VAF 46/58 reads (79%) | catalogued as CD058149, CM106639, COSV57326134, COSV57340615, COSV57378080; called by muse, mutect2, varscan2
- AQP9 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV54967722; called by muse, mutect2, varscan2
- ATF1 | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV50394083; called by muse, mutect2, varscan2
- ATXN3L | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.001); catalogued as rs1279979260, COSV66075300; called by muse, mutect2, varscan2
- BCL2L11 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs778682749, COSV58027966; called by muse, mutect2, varscan2
- BMS1 | c.383T>G p.L128R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65732973; called by muse, mutect2, varscan2
- CCDC158 | c.3158A>T p.D1053V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV66355293; called by muse, mutect2, varscan2
- CCDC158 | c.3158-1G>C p.X1053_splice | Splice Site (SNP) | VAF 23/66 reads (35%) | catalogued as COSV66355120; called by muse, mutect2, varscan2
- CCDC73 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs894958378, COSV58795985; called by muse, mutect2, varscan2
- CDH12 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT tolerated (1); PolyPhen possibly damaging (0.812); catalogued as COSV66390307; called by muse, mutect2, varscan2
- CDH17 | c.2320C>T p.R774W | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.332); catalogued as rs199497492, COSV50325971; called by muse, mutect2, varscan2
- CFAP20 | c.579A>G p.Q193= | Splice Region (SNP) | VAF 44/79 reads (56%) | catalogued as COSV52630557; called by muse, mutect2, varscan2
- COPB1 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs749584129, COSV51446993; called by muse, mutect2, varscan2
- CSMD3 | c.3596G>A p.G1199E (on ENST00000297405 / NM_001363185.1; = p.G1095E on NM_052900.3) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV52113536; called by muse, mutect2, varscan2
- DCLK1 | c.1566C>A p.H522Q | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.487); catalogued as COSV55174373; called by muse, mutect2, varscan2
- DMGDH | c.122C>A p.S41Y | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.003); catalogued as COSV54860991, COSV99668285; called by muse, mutect2, varscan2
- DOK5 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs769217160, COSV52817145; called by muse, mutect2, varscan2
- DYNC2H1 | c.9607A>G p.R3203G | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.542); catalogued as COSV62087563; called by muse, mutect2, varscan2
- ECPAS | c.4477G>A p.E1493K | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs201047834, COSV52191158; called by muse, mutect2, varscan2
- EEA1 | c.2789A>C p.K930T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100467448; called by muse, varscan2
- FAM184A | c.2689A>G p.I897V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV58851978; called by muse, mutect2, varscan2
- FGD4 | c.2147C>T p.S716F | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as COSV56780844; called by muse, mutect2, varscan2
- GRID2 | c.2095T>C p.F699L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56177826; called by muse, mutect2, varscan2
- GTF3C3 | c.1199A>G p.N400S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV55831138; called by mutect2, varscan2
- HLF | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1471376401, COSV56828836; called by muse, mutect2, varscan2
- HMG20A | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV60311559; called by muse, mutect2
- HNRNPA3 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV66820681, COSV66820724; called by muse, mutect2, varscan2
- KBTBD2 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs769428932, COSV58362849; called by muse, mutect2, varscan2
- KLHL1 | c.791G>T p.W264L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.222); catalogued as COSV64767717, COSV64785959; called by muse, mutect2, varscan2
- LEPR | c.580T>G p.C194G | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV60748404; called by muse, mutect2, varscan2
- LILRB1 | c.1188G>T p.E396D (on ENST00000427581; = p.E360D on NM_006669.6) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as COSV61116320, COSV61121382; called by muse, mutect2, varscan2
- LRP2 | c.12493C>T p.R4165C | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs570499038, COSV55543051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP6 | c.3446G>A p.G1149E | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53783988; called by muse, mutect2, varscan2
- MAGEC2 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 124/295 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV55998100; called by muse, mutect2, varscan2
- NAV1 | c.3911A>G p.K1304R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs1267823140, COSV55214556; called by mutect2, varscan2
- NCAM2 | c.1072G>T p.G358W | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53059166; called by muse, mutect2, varscan2
- NRXN1 | c.4159T>C p.Y1387H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.082); catalogued as COSV60486342; called by muse, mutect2, varscan2
- NUDC | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57670921; called by muse, mutect2, varscan2
- OR4C13 | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.039); catalogued as rs1263694888, COSV73648622, COSV73648651; called by muse, mutect2
- PARP12 | c.809A>T p.E270V | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.147); catalogued as COSV54932553; called by muse, mutect2, varscan2
- PCDHA12 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as rs1471783281, COSV56480984; called by muse, mutect2
- PHKB | c.2692G>T p.D898Y | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV54515653; called by muse, mutect2, varscan2
- PILRB | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.387); catalogued as rs750745714, COSV60333328; called by muse, mutect2, varscan2
- PMEL | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.989); catalogued as COSV59384427; called by muse, mutect2, varscan2
- PTPN11 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61005958, COSV61009610; called by muse, mutect2, varscan2
- RASA2 | c.569G>A p.S190N | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV53936819; called by muse, mutect2, varscan2
- RNF213 | c.10730C>T p.S3577F | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV60391532; called by muse, mutect2, varscan2
- RP2 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.045); catalogued as COSV54461010; called by muse, mutect2, varscan2
- RPS6KA6 | c.641T>A p.L214* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV53116763; called by muse, mutect2, varscan2
- SACS | c.3316G>T p.V1106L | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV66535304; called by muse, mutect2, varscan2
- SFXN5 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs781345817, COSV55585071, COSV99729762; called by muse, mutect2, varscan2
- SGK2 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751865521, COSV58312277; called by muse, mutect2
- TAL1 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772071010, COSV53749357; called by muse, mutect2, varscan2
- TCHH | c.4456A>G p.K1486E | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.118); catalogued as COSV64273263; called by muse, mutect2, varscan2
- TCP11L2 | c.772A>T p.S258C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV54429067; called by muse, mutect2, varscan2
- TM9SF4 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs777279514, COSV54104815; called by muse, mutect2
- TMEM267 | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT tolerated (0.14); PolyPhen benign (0.169); catalogued as COSV101231001, COSV67992550; called by muse, mutect2, varscan2
- TPH1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.839); catalogued as rs368665249; called by muse, mutect2, varscan2
- TRPC4 | c.1355A>C p.K452T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58991836; called by muse, mutect2, varscan2
- TRPM6 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 114/201 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as CD134757, COSV62503665; called by muse, mutect2, varscan2
- TUBA1B | c.1316C>A p.S439Y | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV60136367; called by muse, mutect2, varscan2
- VCAN | c.5527G>A p.D1843N | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.038); catalogued as rs140580494; called by muse, mutect2, varscan2
- ZC3H12A | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs916716976, COSV66103922; called by muse, varscan2
- ZFYVE16 | c.4182C>G p.N1394K | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62014372; called by muse, mutect2, varscan2
- GLRA4 | c.1030del p.R344Vfs*62 | Frame Shift Del (DEL) | VAF 54/297 reads (18%) | called by mutect2, pindel*, varscan2
- LGALS9 | c.288del p.M97Cfs*16 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 28/558 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2
- SHC4 | c.1835_1840del p.S612_L613del | In Frame Del (DEL) | VAF 33/101 reads (33%) | called by mutect2, pindel, varscan2
- TMEM100 | c.291_326del p.F98_V109del | In Frame Del (DEL) | VAF 57/147 reads (39%) | called by mutect2, pindel, varscan2
- ZNF488 | c.109A>C p.S37R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATF7 | c.426G>A p.L142= (on ENST00000548446 / NM_001366555.2; = p.L131= on NM_006856.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs1426778203, COSV60642378; called by muse, mutect2, varscan2
- CRISP2 | c.570C>T p.A190= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs371237410; called by muse, mutect2, varscan2
- CSMD1 | c.3003C>T p.T1001= (on ENST00000520002; = p.T1000= on NM_033225.6) | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs751657255, COSV59288299; called by muse, mutect2, varscan2
- FGF19 | c.408C>T p.S136= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as rs769423572, COSV53735818; called by muse, mutect2, varscan2
- IGKV3-20 | c.75G>T p.T25= | Silent (SNP) | VAF 77/140 reads (55%) | catalogued as rs528863405; called by muse, mutect2, varscan2
- KDR | c.2271C>T p.A757= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV55758944; called by muse, mutect2, varscan2
- KMT2A | c.2016C>T p.T672= | Silent (SNP) | VAF 55/93 reads (59%) | catalogued as rs368516174; called by muse, mutect2, varscan2
- LRP1 | c.7701G>A p.K2567= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- LRRK1 | c.4950G>A p.G1650= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs751582278, COSV52603363; called by muse, mutect2
- NAPB | c.831C>T p.T277= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV100582486; called by muse, mutect2, varscan2
- NOMO1 | c.3045C>T p.H1015= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as rs767325995, COSV55057277; called by muse, mutect2, varscan2
- PCDHB12 | c.2055G>T p.S685= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs543195348, COSV53393662, COSV53399217; called by muse, mutect2, varscan2
- PREX1 | c.2631C>T p.R877= | Silent (SNP) | VAF 42/44 reads (95%) | catalogued as rs143006779; called by muse, mutect2, varscan2
- RTL9 | c.2571G>A p.G857= | Silent (SNP) | VAF 226/504 reads (45%) | catalogued as COSV71825426; called by muse, mutect2, varscan2
- SP140 | c.816G>A p.E272= | Silent (SNP) | VAF 75/224 reads (33%) | catalogued as COSV59446733, COSV59446812; called by muse, mutect2, varscan2
- STOML2 | c.135G>A p.E45= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100521268; called by muse, mutect2
- TFAP2D | c.219C>G p.S73= | Silent (SNP) | VAF 57/249 reads (23%) | catalogued as COSV50409005; called by muse, mutect2, varscan2
- TRIM42 | c.804G>A p.S268= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as rs114287544; called by muse, mutect2, varscan2
- TRPC3 | c.519G>A p.A173= (on ENST00000379645 / NM_001366479.2; = p.A100= on NM_003305.2) | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs201407818, COSV53372527; called by muse, mutect2, varscan2
- WDR13 | c.897C>T p.G299= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV54330927; called by muse, mutect2, varscan2
- ZFAT | c.795C>T p.P265= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV64735171; called by muse, mutect2, varscan2
- ZNF544 | c.564C>T p.N188= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV54134415; called by muse, mutect2, varscan2
- SNORD116-1 | n.83G>A | RNA (SNP) | VAF 10/33 reads (30%) | catalogued as rs779206239; called by muse, mutect2, varscan2
- WASF3 | c.717-905G>A | Intron (SNP) | VAF 39/84 reads (46%) | catalogued as rs549292542, COSV58964347; called by muse, mutect2, varscan2
